MMRF case MMRF_2288 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3c3f0b7d-6fdb-4b13-9e20-68b316a0cc94

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Dead; Days to death: 577 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.4 years (21,681 days); ISS stage: III; Days to last known disease status: 577 days (1.6 years); Days to last follow up: 577 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 333 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 32 days; Days to treatment end: 332 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 416 days (1.1 years); Days to treatment end: 466 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 577.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 2): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 146 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.45 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.98 g/L; Beta 2 Microglobulin 6.54 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 92 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 9.8 mmol/L.
- Day 59 (ECOG 1): M Protein 7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Beta 2 Microglobulin 4.75 µg/mL; Lactate Dehydrogenase 9.7 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 89 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 8.2 mmol/L.
- Day 158: M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.53 mg/dL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 97 µmol/L; Blood Urea Nitrogen 6.7 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL.

Other clinical attributes
- Day -26: Weight: 80 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2288_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_2288_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
